TCGA case TCGA-DU-6397 — Brain Lower Grade Glioma (TCGA-LGG)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Henry Ford Hospital. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e695b780-17f4-4e71-9120-7c6bcafaa3a7

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 45 years; Vital status: Dead; Days to death: 1,401 days (3.8 years).

Diagnoses (2)
1. Oligodendroglioma, anaplastic (the primary disease): ICD-O-3 morphology code: 9451/3; ICD-10 code: C71.0; Tissue or organ of origin: Cerebrum; Site of resection or biopsy: Nervous system, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 45.7 years (16,695 days); Year of diagnosis: 1997; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; First symptom longest duration: 0-30 Days; First symptom prior to diagnosis: Headaches; Sites of involvement: Brain, Temporal lobe.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 25 days; Days to treatment end: 69 days; Treatment dose: 5,940 cGy; Course number: 1; Number of fractions: 28; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Brachytherapy, NOS; Initial disease status: Progressive Disease; Days to treatment start: 853 days (2.3 years); Days to treatment end: 853 days (2.3 years); Treatment dose: 4,500 cGy; Course number: 2; Number of fractions: 1; Treatment anatomic sites: Locoregional Site.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Initial disease status: Progressive Disease; Days to treatment start: 884 days (2.4 years); Days to treatment end: 1,219 days (3.3 years); Number of cycles: 12; Treatment dose: 325 mg; Prescribed dose: 150; Prescribed dose units: mg/m2; Route of administration: Oral.
   Recorded as not given: Radiation Therapy, NOS to Head, Face or Neck, NOS, prior to diagnosis.
2. Recurrence of diagnosis 1 (Oligodendroglioma, anaplastic). Age at diagnosis: 48.0 years (17,532 days); Days to diagnosis: 837 days (2.3 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 837 days (2.3 years); Treatment anatomic sites: Locoregional Site.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Radiation Therapy, NOS.
   Recorded as not given: Surgery, NOS to Distant Site.

Follow-up (2 entries)
- Day 837 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 837 days (2.3 years).
- Days to follow up: 1,401 days (3.8 years); Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Risk factors: Headache / Altered Mental Status / Vision Changes.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DU-6397-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.3; Intermediate dimension: 1; Shortest dimension: 0.8.
  Slide TCGA-DU-6397-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0.
  Slide TCGA-DU-6397-01A-01-BS1: Section location: Bottom; Percent tumor cells: 100; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0.
- Sample TCGA-DU-6397-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-DU-6397-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Initial weight: 200 mg.
  Slide TCGA-DU-6397-02A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-DU-6397-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Central nervous system; Histologic diagnosis: Oligodendroglioma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; History ionizing radiation to head: No; Tumor status: With tumor; Tumor site: Supratentorial, Temporal Lobe; Supratentorial localization: Not listed in Medical Record; History seizures: No; History headaches: Yes; Symp changes mental status: Yes; Symp changes visual: Yes; First symptom longest duration: 0 - 30 Days; Family history brain tumor: No; Idh1 mutation test indicator: No.
- Drug treatment: Regimen number: 01; Therapy regimen: Progression.
- Drug treatment, Route of administrations: Route of administration: PO.
- Radiation treatment 2: Radiation type other: Brachytherapy; Therapy regimen: Progression.
- Follow-up form: New tumor event surgery: Yes; Tumor status: With tumor; New tumor event pharmaceutical treatment: Yes; New tumor event radiation treatment: Yes; New tumor event surgery met: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,401 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,401 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 837 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-DU-6397-01A-11D-1704-01): tumor purity 0.79, ploidy 1.94, whole-genome doublings 0.
Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-DU-6397-02A-12D-A36N-01): tumor purity 0.93, ploidy 1.88, whole-genome doublings 0.
